Somatic mutation profile of tumor specimen TCGA-XQ-A8TA-01A (aliquot TCGA-XQ-A8TA-01A-11D-A364-08) from TCGA case TCGA-XQ-A8TA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.9 years (21,889 days).
Specimen TCGA-XQ-A8TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9914154-320c-4c01-958f-e76e9000ed4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XQ-A8TA-10A (Blood Derived Normal), aliquot TCGA-XQ-A8TA-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97bb3f7f-7e9a-4ff8-a2c0-6aa9ee5d7066

The open-access MAF lists 120 somatic variants for this specimen: 94 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 24, Nonsense Mutation 6, Splice Site 3, RNA 1, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.1100C>A p.T367N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV100741779; called by muse, mutect2, varscan2
- ACKR2 | c.769G>C p.V257L | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV99825531; called by muse, mutect2, varscan2
- ACSS2 | c.1299G>T p.Q433H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99489852; called by muse, mutect2, varscan2
- ADGRB3 | c.605T>C p.L202S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.969); catalogued as COSV101000710; called by muse, mutect2, varscan2
- AHDC1 | c.4312G>C p.A1438P | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV99899296; called by muse, mutect2
- ANO4 | c.2007-1G>A p.X669_splice (on ENST00000392977 / NM_001286615.2; = p.X634_splice on NM_178826.4) | Splice Site (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100152870; called by muse, mutect2, varscan2
- AP4E1 | c.647A>C p.D216A | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99956631; called by muse, mutect2, varscan2
- APC | c.4565T>G p.L1522* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV57357937; called by muse, mutect2, varscan2
- ARSB | c.783G>C p.K261N | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV99364760; called by muse, mutect2, varscan2
- B3GNT9 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376245125, COSV99531337; called by muse, mutect2
- BRCA1 | c.543A>C p.E181D | Missense Mutation (SNP) | VAF 146/258 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100524144; called by muse, mutect2, varscan2
- CACNA1B | c.1039A>G p.M347V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.977); catalogued as COSV99497379; called by muse, mutect2
- CCN4 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs760709240, COSV51529438, COSV99137085; called by muse, mutect2, varscan2
- CCR1 | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99946707; called by muse, mutect2, varscan2
- CDC42BPB | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV100775440, COSV100775527; called by muse, mutect2
- CENPJ | c.2712G>C p.Q904H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101121511; called by muse, mutect2, varscan2
- CEP250 | c.7220T>A p.L2407Q | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698929; called by muse, mutect2
- CMTR2 | c.1597T>G p.L533V | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100579146; called by muse, mutect2, varscan2
- COL6A3 | c.6472-1G>T p.X2158_splice | Splice Site (SNP) | VAF 101/112 reads (90%) | catalogued as COSV55083344; called by muse, mutect2, varscan2
- CSMD3 | c.1463A>T p.D488V (on ENST00000297405 / NM_001363185.1; = p.D384V on NM_052900.3) | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99834182; called by muse, mutect2, varscan2
- DENND4B | c.4460G>C p.R1487P | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100768658, COSV63411501; called by muse, mutect2, varscan2
- DGKI | c.854G>T p.S285I | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99934465; called by muse, mutect2, varscan2
- DHRS7C | c.646G>A p.V216I (on ENST00000330255 / NM_001220493.2; = p.V215I on NM_001105571.3) | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100364685; called by muse, mutect2, varscan2
- ERLEC1 | c.669T>G p.I223M | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99483032; called by muse, mutect2, varscan2
- ESPL1 | c.2845A>G p.I949V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as rs1379301643, COSV99229313; called by muse, mutect2, varscan2
- FAM71F2 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV101100692; called by muse, varscan2
- FES | c.2177G>T p.W726L | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183074; called by muse, mutect2
- FLVCR2 | c.892T>G p.L298V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99471295; called by muse, mutect2, varscan2
- FMO2 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as rs753045493, COSV99269124; called by muse, mutect2, varscan2
- GAS8 | c.1155C>G p.F385L | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1296965964, COSV99243969; called by muse, mutect2, varscan2
- GPR87 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99608802; called by mutect2, varscan2
- HECW1 | c.2540A>T p.Y847F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs770034480, COSV101223525; called by muse, mutect2, varscan2
- HERC2 | c.8338G>T p.D2780Y | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV99873714; called by muse, mutect2, varscan2
- IGKV1-6 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs371823662; called by muse, mutect2, varscan2
- IL16 | c.3772G>A p.D1258N (on ENST00000302987 / NM_172217.5; = p.D557N on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100250832; called by muse, mutect2, varscan2
- INSIG2 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV99830530; called by muse, mutect2, varscan2
- KANSL1L | c.2259G>C p.Q753H | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV99910552; called by muse, mutect2, varscan2
- KCNC1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 48/58 reads (83%) | catalogued as COSV99789273; called by muse, mutect2, varscan2
- KRT78 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV58851652; called by muse, mutect2, varscan2
- L1CAM | c.3129C>G p.C1043W | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100649134, COSV62829890; called by muse, mutect2, varscan2
- MAP7 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs773646433, COSV100643875, COSV100644066; called by muse, mutect2, varscan2
- MAP7D3 | c.2009A>T p.Q670L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV100286343; called by muse, mutect2, varscan2
- MET | c.2646T>G p.C882W | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100577215; called by muse, mutect2, varscan2
- METTL18 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53679562; called by muse, mutect2, varscan2
- MGAM | c.4246G>T p.G1416C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1348494719, COSV101527489; called by muse, mutect2, varscan2
- MIDEAS | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs970184409, COSV99678888; called by muse, mutect2, varscan2
- MUC17 | c.4934G>C p.S1645T | Missense Mutation (SNP) | VAF 128/241 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV100073211, COSV60283431, COSV60283750; called by muse, mutect2, varscan2
- MYOZ1 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.483); catalogued as rs376703108; called by mutect2, varscan2
- NDST4 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs1230951099, COSV99996479; called by muse, mutect2, varscan2
- NFATC2 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.362); catalogued as COSV65353700, COSV65357899, COSV65359449; called by muse, mutect2, varscan2
- NR1D2 | c.1325C>A p.T442N | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100437453; called by muse, mutect2
- NRG2 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 77/81 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769231072, COSV99180262; called by muse, mutect2, varscan2
- OBSCN | c.2855C>G p.A952G | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs775213457, COSV52832463; called by muse, mutect2, varscan2
- OBSCN | c.5646C>A p.S1882R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs865935487, COSV99477895; called by muse, mutect2, varscan2
- OR4D2 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs773297564, COSV101613856, COSV73459861; called by muse, mutect2, varscan2
- OR5K2 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV101415968; called by muse, mutect2, varscan2
- PAPPA2 | c.1615A>T p.N539Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.181); catalogued as COSV100866784; called by muse, mutect2, varscan2
- PCDHB11 | c.234C>G p.D78E | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV99504292; called by muse, mutect2, varscan2
- PIGO | c.1590G>C p.W530C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99956666; called by muse, mutect2, varscan2
- PIK3R2 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99717416; called by muse, mutect2, varscan2
- PLCB4 | c.2504T>G p.L835* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99595469; called by muse, mutect2, varscan2
- PLEKHS1 | c.980C>A p.P327H (on ENST00000369310 / NM_182601.1; = p.P347H on NM_024889.5) | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.105); catalogued as COSV100613114, COSV63054166; called by muse, mutect2, varscan2
- PPP4R4 | c.1766C>A p.T589N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs1299887773, COSV100428610; called by muse, mutect2, varscan2
- PRDM8 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1325914002, COSV60203742; called by muse, mutect2, varscan2
- PSMA6 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV54838689; called by muse, mutect2
- RASGEF1B | c.1245G>C p.W415C | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV100020970; called by muse, mutect2
- SCMH1 | c.1451A>G p.H484R (on ENST00000326197 / NM_001031694.2; = p.H437R on NM_012236.4) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100401738; called by muse, mutect2, varscan2
- SCN11A | c.2459A>G p.N820S | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV100181552; called by muse, mutect2
- SLC7A14 | c.539T>G p.L180R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV99200512, COSV99200626; called by muse, mutect2, varscan2
- SLC9C2 | c.403A>T p.I135F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV100876748, COSV104424447; called by muse, mutect2
- SLIT3 | c.2147A>T p.E716V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs1428081990, COSV100267441; called by muse, varscan2
- SORL1 | c.5821G>A p.V1941I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV99493851; called by muse, mutect2, varscan2
- SSRP1 | c.1553A>G p.K518R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV99554912; called by muse, mutect2
- STK36 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs371599500, COSV99829011; called by muse, mutect2, varscan2
- TAF5L | c.608A>G p.K203R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99273160; called by muse, mutect2, varscan2
- THSD1 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.82); PolyPhen benign (0.054); catalogued as rs914609200, COSV51626314; called by muse, mutect2, varscan2
- TLL2 | c.1845G>A p.M615I | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100780289; called by muse, mutect2, varscan2
- TMEM132D | c.3077A>C p.D1026A | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.23); catalogued as COSV101242828; called by muse, mutect2, varscan2
- TNFRSF21 | c.1136A>T p.K379M | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57281748, COSV99729631; called by muse, mutect2, varscan2
- TRIM71 | c.1742A>T p.K581M | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV101070434; called by muse, mutect2, varscan2
- TRPV6 | c.233T>G p.L78R | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100844295; called by muse, mutect2, varscan2
- TTN | c.79264C>G p.R26422G (on ENST00000591111; = p.R18998G on NM_003319.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen benign (0.025); catalogued as COSV100612438, COSV60295860; called by muse, mutect2, varscan2
- TUBG1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52220693; called by muse, mutect2, varscan2
- VHL | c.393C>G p.N131K | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as CM042502, CX073799, COSV56548229, COSV56549993; called by muse, mutect2
- VTCN1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs748959440, COSV60225190; called by muse, mutect2, varscan2
- WASHC5 | c.3092T>A p.I1031K | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100572824; called by muse, mutect2, varscan2
- WDR72 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100854455, COSV64753928; called by muse, mutect2, varscan2
- YIPF6 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 108/112 reads (96%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV101006242; called by muse, mutect2, varscan2
- ZC3H4 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99452297; called by muse, mutect2, varscan2
- ZDBF2 | c.762T>A p.H254Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100984850; called by muse, mutect2
- GCH1 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2
- KRT85 | c.950_951+10del p.X317_splice | Splice Site (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel
- RNF8 | c.440dup p.N147Kfs*2 | Frame Shift Ins (INS) | VAF 22/44 reads (50%) | called by mutect2, varscan2
- TAB2 | c.910_930del p.S304_S310del | In Frame Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- ACTR3 | c.891A>T p.S297= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV99603597; called by muse, mutect2, varscan2
- AFF3 | c.204G>C p.R68= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as COSV100418838, COSV57860898; called by muse, mutect2, varscan2
- ALDH1B1 | c.1047G>A p.G349= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs199975848, COSV100890942; called by muse, mutect2, varscan2
- ANK1 | c.2451G>T p.S817= | Silent (SNP) | VAF 30/32 reads (94%) | catalogued as COSV55882239, COSV99225240; called by muse, mutect2, varscan2
- BOD1L1 | c.3768G>A p.L1256= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV50063027, COSV99239361; called by muse, mutect2, varscan2
- BTBD16 | c.555C>G p.S185= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV99584789; called by muse, mutect2, varscan2
- C3orf56 | c.336C>T p.D112= | Silent (SNP) | VAF 34/197 reads (17%) | catalogued as COSV101228959; called by muse, mutect2, varscan2
- CDK12 | c.3045A>G p.L1015= | Silent (SNP) | VAF 34/44 reads (77%) | catalogued as rs757636720, COSV101420448; called by muse, mutect2, varscan2
- ECPAS | c.675T>C p.G225= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as COSV99398265; called by muse, mutect2, varscan2
- ELF4 | c.1869C>T p.S623= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV57456016; called by muse, mutect2, varscan2
- FAM71F2 | c.78T>C p.L26= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV101100693, COSV104430117; called by muse, varscan2
- HEPACAM | c.507A>C p.S169= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV100005708, COSV53430358; called by muse, mutect2, varscan2
- HERC2 | c.8337G>T p.L2779= | Silent (SNP) | VAF 73/162 reads (45%) | catalogued as rs1338096023, COSV99873719; called by muse, mutect2, varscan2
- MLC1 | c.1089C>T p.D363= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV100286350; called by muse, mutect2, varscan2
- MMRN1 | c.408T>C p.N136= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV99307100; called by muse, mutect2, varscan2
- MYH2 | c.819G>A p.K273= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99820118; called by muse, mutect2
- NPY5R | c.859A>C p.R287= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV100642771; called by muse, mutect2, varscan2
- PBRM1 | c.3870C>T p.Y1290= (on ENST00000296302 / NM_001366071.2; = p.Y1265= on NM_018313.5) | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV99968775; called by muse, mutect2, varscan2
- PLEKHS1 | c.981T>G p.P327= (on ENST00000369310 / NM_182601.1; = p.P347= on NM_024889.5) | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as COSV100613118; called by muse, mutect2, varscan2
- PRTFDC1 | c.378C>T p.G126= | Silent (SNP) | VAF 127/280 reads (45%) | catalogued as rs201109414, COSV60775699; called by muse, mutect2, varscan2
- PTPN9 | c.75G>A p.Q25= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs1269035303, COSV100144313; called by muse, mutect2, varscan2
- SF3B3 | c.1638G>A p.K546= | Silent (SNP) | VAF 75/127 reads (59%) | catalogued as COSV100209859; called by muse, mutect2, varscan2
- WDR31 | c.1053C>G p.L351= (on ENST00000374193 / NM_001006615.3; = p.L350= on NM_145241.5) | Silent (SNP) | VAF 54/89 reads (61%) | catalogued as COSV100516693; called by muse, mutect2, varscan2
- ZNF556 | c.486G>A p.L162= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV100298735; called by muse, mutect2, varscan2
- ASIC2 | c.556-179585G>T | Intron (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- VN1R10P | n.758C>G | RNA (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
